Surgical pathology report (de-identified scan), TCGA case TCGA-V5-AASW, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Duke University, specimen TCGA-V5-AASW-01A (Primary Tumor).

[page 1 of 2]
172

Electronically signed by

at

Sign off status: Completed

Patient:

DOB

Provider:

FINAL RESULT

PHYSICIAN INFORMATION

Requesting: endoscopy center, east carolina
gastroenterology
Ordering:

PATIENT INFORMATION

Name:
DOB:
Sex: male
Tel:

REPORT DETAILS

Name:
Accession ID:
Lab Ref Id:

REPORT DATES

Order:
Collection:
Report:
Result:

ICD.O-3
Adenocarcinoma NOS 8140/3
Esophagus NOS C15.9
Data with Esophagus, distal third
C15.5
JAN 4/18/14

NAME

VALUE

Comment

Material submitted:

PART A: Upper GI Biopsy, Esophagus, Lower/Distal
PART B: Upper GI Biopsy, Esophagus, E-G Junct.
PART C: Upper GI Biopsy, Esophagus, Proximal

Comment

Diagnosis:

- A. ESOPHAGEAL TISSUE WITH AT LEAST INTRAMUCOSAL ADENOCARCINOMA. PLEASE SEE COMMENT.
B. BARRETT'S ESOPHAGUS. POSITIVE FOR DYSPLASIA, HIGH GRADE.
C. ESOPHAGEAL TISSUE WITH ADENOCARCINOMA, POORLY DIFFERENTIATED. DEPTH OF INVASION CANNOT BE ASSESSED DUE TO THE NATURE AND SIZE OF THE SPECIMEN.

Comment:

- A. In view of the superficial nature of the biopsy, the possibility of an underlying or nearby invasive lesion cannot be excluded.

Comment

Electronically signed:

A.

Comment

[page 2 of 2]
272

Gross description:

- A. Received in formalin are 4 fragments of tan, soft tissue measuring 0.7 x 0.3 x 0.2 cm to 0.1 x 0.1 x 0.1 cm and submitted in toto in 1 cassette. Minute specimen, may not survive processing.
- B. Received in formalin are 3 fragments of tan, soft tissue measuring 0.5 x 0.2 x 0.1 cm to 0.1 x 0.1 x 0.1 cm and submitted in toto in 1 cassette. Minute specimen, may not survive processing.
- C. Received in formalin are 3 fragments of tan, soft tissue measuring 0.4 x 0.3 x 0.1 cm to 0.2 x 0.2 x 0.1 cm and submitted in toto in 1 cassette.

Comment

Microscopic:

- A. Irregularly shaped glands, some forming cribriform structures, are present. They are lined by atypical cells which show disordered stratification and a loss of nuclear polarity. Individual malignant cells have extended beyond the basement membrane into the lamina propria and/or muscularis mucosa but are not seen to extend into the submucosa.
- B. Columnar-lined mucosa composed of gastric type of surface cells with intestinal metaplasia characterized by interspersed goblet cells which is characteristic of the specialized epithelium of Barrett's. Some areas have glands showing nuclear hyperchromaticity and pseudostratification, with the nuclei seen extending to the surface of the gland lumen. These changes are seen to extend onto the surface of the specimen, and there is also significant glandular crowding. No invasive activity is seen.
- C. There is a tumor composed of irregularly-shaped sheets of pleomorphic cells, some showing gland-like structures, which infiltrate the mucosa. Occasional mucin production is noted. Mitotic activity is brisk and tumor necrosis is evident.

Comment

Pathologist provided ICD-9:

150.9 MALIG NEOPLASM ESOPH UNSPEC SITE

Comment

CPT

88305x3

ADDITIONAL NOTES

Patient: [REDACTED]

Source: NCI Genomic Data Commons file 2bc6b4eb-6985-406b-a344-99db494842e4 (TCGA-V5-AASW.19324D50-7E95-4270-99C1-D52532616DAD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).